Somatic mutation profile of tumor specimen ALCH-ABRV-TTP1-A (aliquot ALCH-ABRV-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABRV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.2 years (26,386 days).
Specimen ALCH-ABRV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e7fd29f-2181-4c30-b3a7-9faed39d5102.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABRV-NB1-A (Blood Derived Normal), aliquot ALCH-ABRV-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/822383ee-2145-44fb-b01b-e67bdab55176

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, 3'UTR 2, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT5 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481622632; called by muse, mutect2
- EME2 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs370196251; called by muse, mutect2, varscan2
- FAT2 | c.4886C>T p.T1629I | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs756734531, COSV55831716; called by muse, mutect2, varscan2
- GPRASP2 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs142784436; called by muse, mutect2
- NLGN4X | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.899); catalogued as COSV52029040, COSV99320313; called by muse, mutect2, varscan2
- OR2T6 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV63216855; called by muse, mutect2
- PKHD1L1 | c.10705C>T p.P3569S | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs866043029, COSV65740670; called by muse, mutect2
- SLIT1 | c.4027C>T p.R1343C | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs983319396; called by muse, mutect2, varscan2
- C3orf20 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- DERPC | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- GRIP1 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- HUWE1 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- MYO1H | c.1644+2T>C p.X548_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- NEK4 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RALGPS2 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- SMPD4 | c.1096G>A p.V366M (on ENST00000409031 / NM_017951.4; = p.V337M on NM_017751.4) | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SYNE2 | c.7472T>C p.L2491P | Missense Mutation (SNP) | VAF 20/534 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- CYP11B1 | c.942G>T p.G314= | Silent (SNP) | VAF 24/392 reads (6%) | called by muse, mutect2
- FSIP2 | c.15511C>A p.R5171= | Silent (SNP) | VAF 15/258 reads (6%) | called by muse, mutect2
- LRRTM3 | c.1575C>T p.Y525= | Silent (SNP) | VAF 33/280 reads (12%) | catalogued as rs374443522; called by muse, mutect2, varscan2
- SLC9A3 | c.1116C>G p.L372= | Silent (SNP) | VAF 18/106 reads (17%) | called by mutect2, varscan2
- TENT5D | c.348A>T p.V116= | Silent (SNP) | VAF 44/449 reads (10%) | called by muse, mutect2
- ZFP90 | c.1398T>C p.T466= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs1186087053; called by muse, mutect2, varscan2
- CEACAM4 | c.*37G>A | 3'UTR (SNP) | VAF 10/63 reads (16%) | catalogued as rs200632223; called by muse, mutect2, varscan2
- PRPS1 | c.*13T>C | 3'UTR (SNP) | VAF 24/333 reads (7%) | called by muse, mutect2
- UBE2DNL | n.409A>T | RNA (SNP) | VAF 30/614 reads (5%) | called by muse, mutect2
